Somatic mutation profile of tumor specimen MP2PRT-PAVVZK-TMP1-A (aliquot MP2PRT-PAVVZK-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVVZK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,095 days).
Specimen MP2PRT-PAVVZK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 293152a9-c1ca-4fa6-9401-4a7adfe69d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVVZK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVVZK-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eea390b-86c4-4875-b5e5-5e377a2375cb

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1, 5'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.2920G>A p.V974I | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs777581994; called by muse, mutect2, varscan2
- DNAH17 | c.8855C>T p.T2952M | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs756326276; called by muse, mutect2
- ITPRIPL2 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67347803; called by muse, mutect2
- PHF3 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 9/226 reads (4%) | catalogued as COSV100012794; called by muse, mutect2
- ZNF611 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100160596; called by muse, mutect2
- AGTR2 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 100/125 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEST1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- CCNA2 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.2127G>C p.K709N | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- IGHV4-34 | c.366_367insTCGCG p.R123Sfs*? | Frame Shift Ins (INS) | VAF 30/33 reads (91%) | called by pindel, varscan2
- LRRC45 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- RBM5 | c.1316A>G p.Q439R | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC16A12 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2
- SLC4A2 | c.1465C>G p.P489A | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- UNC80 | c.4715C>G p.P1572R | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV4-34 | c.339C>T p.A113= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as rs1214739817; called by muse, varscan2
- TGFBR3 | c.1515C>T p.C505= | Silent (SNP) | VAF 90/228 reads (39%) | catalogued as rs773132708, COSV53028799; called by muse, mutect2, varscan2
- ZNF33A | c.186C>T p.F62= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs200514214; called by muse, mutect2, varscan2
- TSC1 | c.-124G>C | 5'UTR (SNP) | VAF 91/175 reads (52%) | called by muse, mutect2, varscan2
- VSTM4 | c.457+3843G>C | Intron (SNP) | VAF 86/168 reads (51%) | catalogued as COSV100039155; called by muse, mutect2, varscan2
